Somatic mutation profile of tumor specimen TCGA-BR-A44T-01A (aliquot TCGA-BR-A44T-01A-32D-A24D-08) from TCGA case TCGA-BR-A44T, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 53.1 years (19,407 days).
Specimen TCGA-BR-A44T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0da1f2d0-e79d-4f71-b22a-b486555969b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A44T-10A (Blood Derived Normal), aliquot TCGA-BR-A44T-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/010f5e2d-0b95-4055-aa94-35ce9e28fd78

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC3 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV66559181; called by muse, mutect2
- CDH1 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55730487; called by muse, mutect2
- DNMBP | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV60623412; called by muse, mutect2
- FAT2 | c.11083G>A p.E3695K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61743252; called by muse, mutect2
- GABRB1 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.059); catalogued as COSV54976720, COSV54977952; called by muse, mutect2
- ICAM5 | c.1424A>T p.D475V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55746726; called by muse, mutect2
- SHROOM4 | c.2512C>A p.H838N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.932); catalogued as COSV56783518, COSV56787337; called by muse, mutect2
- LRRC8E | c.1731C>T p.S577= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV60717538; called by muse, mutect2
- PCDHB3 | c.2124C>T p.F708= | Silent (SNP) | VAF 18/415 reads (4%) | catalogued as rs782371087, COSV50566330; called by muse, mutect2
- RMND5A | c.1047C>T p.P349= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV52153345; called by muse, mutect2
- TMEM168 | c.517T>C p.L173= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV57180113; called by muse, mutect2
- ZFYVE26 | c.6648G>A p.K2216= | Silent (SNP) | VAF 31/588 reads (5%) | catalogued as COSV61326730; called by muse, mutect2
- ZNF536 | c.3207C>A p.I1069= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs1321412404, COSV62821909, COSV62831603; called by muse, mutect2
- EP400 | c.5755-729C>T | Intron (SNP) | VAF 10/292 reads (3%) | catalogued as COSV100200455; called by muse, mutect2
